Somatic mutation profile of tumor specimen TCGA-DD-AADB-01A (aliquot TCGA-DD-AADB-01A-11D-A40R-10) from TCGA case TCGA-DD-AADB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 51.3 years (18,728 days).
Specimen TCGA-DD-AADB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1f43120-dbef-4cf0-80b7-410b3ee9a039.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADB-10A (Blood Derived Normal), aliquot TCGA-DD-AADB-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa6ffa44-5703-4026-b1b4-ddc5047e8e46

The open-access MAF lists 143 somatic variants for this specimen: 103 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 39, Nonsense Mutation 8, Splice Site 6, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1244A>G p.Y415C (on ENST00000272895 / NM_173076.3; = p.Y97C on NM_015657.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.302); catalogued as rs1294829369, COSV99791986; called by muse, mutect2, varscan2
- ABCA13 | c.8918C>T p.A2973V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.084); catalogued as COSV101447215; called by muse, mutect2, varscan2
- ADGRF1 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99347605; called by muse, mutect2
- ADGRF1 | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV99347610; called by muse, mutect2
- ANGEL2 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751644663, COSV100853952; called by muse, mutect2, varscan2
- ANGPTL4 | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100035269; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1264330150; called by muse, mutect2, varscan2
- ARL6IP4 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.965); catalogued as COSV99759643; called by muse, mutect2
- ATP13A5 | c.2381A>T p.H794L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100665718; called by muse, mutect2, varscan2
- ATXN7L2 | c.1573T>A p.C525S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.966); catalogued as COSV100149936; called by muse, mutect2, varscan2
- B3GALT5 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs545552313, COSV100563230; called by muse, mutect2, varscan2
- BANK1 | c.1829G>C p.R610T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536855; called by muse, mutect2
- BTBD11 | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99776993; called by muse, mutect2, varscan2
- C2CD3 | c.2626A>G p.N876D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100487417; called by muse, mutect2, varscan2
- CACNA1G | c.4386G>A p.W1462* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100662546; called by muse, mutect2, varscan2
- CACNA2D1 | c.2885A>G p.D962G (on ENST00000356253 / NM_001366867.1; = p.D950G on NM_000722.4) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV100667297; called by muse, mutect2, varscan2
- CALB1 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs767520923, COSV55367285, COSV55370424, COSV99618618; called by muse, mutect2, varscan2
- CCNT1 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99980907; called by muse, mutect2, varscan2
- CDC25C | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100086917; called by muse, mutect2, varscan2
- CDCA5 | c.39G>T p.Q13H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99298042; called by muse, mutect2, varscan2
- CDH11 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV51764953; called by muse, mutect2, varscan2
- CDK13 | c.2608T>A p.Y870N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99476088; called by muse, mutect2, varscan2
- CFAP94 | c.1351C>G p.P451A (on ENST00000320267 / NM_001352064.2; = p.P457A on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209744; called by muse, mutect2, varscan2
- COL17A1 | c.4382C>A p.P1461Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as COSV100212114; called by muse, mutect2, varscan2
- COL7A1 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1177397879, COSV100097686; called by muse, mutect2, varscan2
- COMMD2 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV101511907; called by muse, mutect2, varscan2
- CP | c.1152C>G p.N384K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV99224476; called by muse, mutect2, varscan2
- CPSF1 | c.3649A>G p.S1217G | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100450708; called by muse, mutect2, varscan2
- D2HGDH | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV100344934; called by muse, mutect2
- DAAM2 | c.2723A>C p.K908T (on ENST00000274867 / NM_001201427.2; = p.K907T on NM_015345.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV99227010; called by muse, mutect2, varscan2
- DMXL1 | c.8258A>G p.H2753R | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100224953; called by muse, mutect2, varscan2
- DYNC2I1 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV101337727; called by muse, mutect2, varscan2
- EHBP1L1 | c.3277A>T p.N1093Y | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100500024; called by muse, mutect2, varscan2
- EHD1 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1389025678, COSV100277268; called by muse, mutect2, varscan2
- EP400 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1323197385, COSV100202249; called by mutect2, varscan2
- ERBB4 | c.2012T>C p.F671S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99632696; called by muse, mutect2, varscan2
- ETHE1 | c.505+2T>A p.X169_splice | Splice Site (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99417564; called by muse, mutect2, varscan2
- FSCB | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV100469871; called by mutect2, varscan2
- GEN1 | c.2248G>T p.V750F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1047211166, COSV58056799; called by muse, mutect2, varscan2
- GRIK4 | c.1976T>G p.L659R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101483770; called by muse, mutect2, varscan2
- H2BC14 | c.82A>T p.K28* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100297680; called by muse, mutect2, varscan2
- IL2RA | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs776999325, COSV99906902; called by muse, mutect2, varscan2
- INSRR | c.2089C>A p.Q697K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV100948080; called by muse, mutect2, varscan2
- IQGAP3 | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100752370; called by muse, mutect2, varscan2
- IRF6 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54214019; called by muse, mutect2, varscan2
- IRX4 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99181848; called by muse, mutect2, varscan2
- KIF21B | c.4276A>G p.M1426V (on ENST00000422435 / NM_001252100.2; = p.M1413V on NM_017596.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100145133; called by muse, mutect2, varscan2
- LGR6 | c.1070+2T>A p.X357_splice (on ENST00000367278 / NM_001017403.1; = p.X305_splice on NM_021636.3) | Splice Site (SNP) | VAF 23/102 reads (23%) | catalogued as COSV55151617, COSV99707869; called by muse, mutect2, varscan2
- LILRB5 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.514); catalogued as rs747129896, COSV100300810; called by muse, mutect2, varscan2
- LUM | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899191; called by muse, mutect2, varscan2
- MACROD2 | c.1079A>T p.N360I (on ENST00000642719; = p.N332I on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV99443269; called by muse, mutect2, varscan2
- MAP2K6 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100765141; called by muse, mutect2, varscan2
- MAP3K3 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368725; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1883A>T p.Q628L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99571778; called by muse, mutect2, varscan2
- MEIS1 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99715797; called by muse, mutect2, varscan2
- MGAM | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 75/249 reads (30%) | catalogued as COSV101527748; called by muse, mutect2, varscan2
- MTCL1 | c.1255C>T p.R419* (on ENST00000306329 / NM_001378206.1; = p.R59* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60407418; called by muse, mutect2, varscan2
- MTX3 | c.228G>A p.Q76= | Splice Region (SNP) | VAF 61/278 reads (22%) | catalogued as COSV101560518; called by muse, mutect2, varscan2
- MYCL | c.217G>T p.A73S (on ENST00000372816 / NM_001033081.3; = p.A103S on NM_005376.5) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as COSV100862393; called by muse, mutect2, varscan2
- MYH6 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs746593504, COSV100676987; called by muse, mutect2, varscan2
- NBEA | c.1148T>G p.F383C | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100084131; called by muse, mutect2
- NBEA | c.5309C>A p.P1770Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.005); catalogued as COSV100084134, COSV59830408; called by muse, mutect2, varscan2
- NEMP1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100272302, COSV55663735; called by muse, mutect2, varscan2
- NIM1K | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100390459; called by muse, mutect2, varscan2
- NR3C1 | c.1552A>T p.K518* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV99196703; called by muse, mutect2, varscan2
- OPCML | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100104956; called by muse, mutect2, varscan2
- OR51G1 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1329562947, COSV58969859; called by muse, mutect2, varscan2
- OR5H1 | c.658T>A p.F220I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100641773; called by muse, mutect2, varscan2
- OR6A2 | c.529A>T p.N177Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100215824; called by muse, mutect2, varscan2
- PCDH15 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100225737; called by muse, mutect2, varscan2
- PCLO | c.4462C>T p.P1488S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61619060; called by muse, mutect2, varscan2
- PLA2R1 | c.1147A>G p.N383D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV99323570; called by muse, mutect2, varscan2
- PLA2R1 | c.402T>G p.H134Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99323571; called by muse, mutect2, varscan2
- PLEC | c.10721G>A p.R3574K (on ENST00000322810 / NM_201380.4; = p.R3464K on NM_000445.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100518855; called by muse, mutect2, varscan2
- PPP1R17 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100566475; called by muse, mutect2, varscan2
- PREX1 | c.2147C>A p.P716Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs775874146, COSV100906395; called by muse, mutect2, varscan2
- PTGR1 | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99437635; called by muse, mutect2, varscan2
- PTPRZ1 | c.1910C>A p.S637* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV101100841; called by muse, mutect2, varscan2
- RC3H2 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100106923; called by muse, mutect2, varscan2
- RCCD1 | c.143G>A p.W48* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV101263245; called by muse, mutect2, varscan2
- SLC1A7 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100439838; called by muse, mutect2, varscan2
- SLC34A2 | c.2062A>G p.T688A | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV101158457; called by muse, mutect2, varscan2
- SLC5A4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV56674085; called by muse, mutect2, varscan2
- SLCO4C1 | c.783C>A p.H261Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as COSV60520465; called by muse, mutect2
- SPCS3 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV101543709; called by muse, mutect2, varscan2
- SPPL2B | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101476117; called by muse, mutect2, varscan2
- SRSF1 | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.726); catalogued as COSV99365487; called by muse, mutect2, varscan2
- SVEP1 | c.5468G>A p.G1823E | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV99929796; called by muse, mutect2, varscan2
- TATDN3 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.637); catalogued as COSV100875278; called by muse, mutect2, varscan2
- TMEM214 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1012642661, COSV99476528; called by muse, mutect2, varscan2
- TMEM72 | c.210-1G>T p.X70_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV101273596; called by muse, mutect2, varscan2
- TNN | c.784+1G>A p.X262_splice | Splice Site (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99512983; called by muse, mutect2, varscan2
- TSNARE1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs750524448, COSV100211470; called by muse, mutect2, varscan2
- UNC80 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55884892, COSV99780961; called by muse, mutect2, varscan2
- USP20 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.15); catalogued as rs759233131, COSV100204763; called by muse, mutect2, varscan2
- ZNF182 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100527219; called by muse, mutect2
- ZNF419 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99692618; called by muse, mutect2, varscan2
- ZNF592 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100246123; called by muse, mutect2, varscan2
- ZP4 | c.1529C>A p.A510E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV100850777; called by muse, mutect2, varscan2
- ALB | c.1787_1823del p.X596_splice | Splice Site (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel
- MFSD4A | c.1484del p.P495Hfs*24 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3608G>T p.S1203I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by mutect2, varscan2
- ABHD5 | c.384G>A p.E128= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV50006816, COSV99185494; called by muse, mutect2, varscan2
- ACACB | c.5946C>T p.G1982= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs759684564, COSV58142332; called by muse, mutect2, varscan2
- ACLY | c.1527G>T p.V509= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100709904; called by muse, mutect2, varscan2
- AL359922.1 | c.369A>T p.S123= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- ALMS1 | c.7077T>A p.V2359= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100043704; called by muse, mutect2, varscan2
- ATP1A2 | c.249A>G p.T83= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100768155; called by muse, mutect2, varscan2
- C9orf131 | c.2637G>A p.R879= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100398312; called by muse, mutect2, varscan2
- COA1 | c.201T>C p.P67= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs564919110, COSV99786719; called by muse, mutect2, varscan2
- COLEC12 | c.996G>A p.L332= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101232069; called by muse, mutect2, varscan2
- DFFA | c.543A>G p.Q181= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100986696; called by muse, mutect2, varscan2
- DSCAML1 | c.339C>A p.P113= (on ENST00000321322; = p.P53= on NM_020693.4) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100357233; called by muse, mutect2, varscan2
- DUSP5 | c.141C>T p.L47= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100851859, COSV100851939, COSV63646590; called by muse, mutect2, varscan2
- FOLR1 | c.306G>A p.Q102= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100398591; called by muse, mutect2, varscan2
- GJC1 | c.25C>T p.L9= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1567707619, COSV100395247; called by muse, varscan2
- ITGAM | c.57G>A p.L19= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99793139; called by muse, mutect2, varscan2
- IVL | c.1611G>A p.K537= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100908265; called by muse, mutect2, varscan2
- LGALS4 | c.270G>A p.K90= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV100313370; called by muse, mutect2, varscan2
- MACROH2A2 | c.663C>T p.A221= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs988498144, COSV100951966; called by muse, mutect2, varscan2
- MIA2 | c.882A>G p.L294= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99696932; called by muse, mutect2, varscan2
- MUC6 | c.5187C>T p.T1729= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV70143465; called by muse, mutect2, varscan2
- MYLK3 | c.1788G>A p.E596= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1278355686, COSV101189214; called by muse, mutect2, varscan2
- NDST4 | c.2346C>A p.V782= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99997858; called by muse, mutect2
- OBSCN | c.105T>G p.G35= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV99484149; called by muse, mutect2, varscan2
- OR9G1 | c.408C>A p.S136= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV56454938; called by muse, mutect2
- PARVB | c.399G>C p.L133= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV100115231; called by muse, mutect2, varscan2
- PCDHA10 | c.495A>G p.A165= | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as rs1364522984, COSV100254364; called by muse, mutect2, varscan2
- PIK3CG | c.1968T>C p.V656= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100783179; called by muse, mutect2, varscan2
- PRDM11 | c.177G>T p.T59= (on ENST00000530656 / NM_001359633.1; = p.T25= on NM_001256695.1) | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV55437066, COSV99771102; called by muse, mutect2, varscan2
- SCN4A | c.858G>A p.P286= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs560230431, COSV71129922; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLC27A5 | c.1647C>T p.D549= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV99564612; called by muse, mutect2, varscan2
- SNX7 | c.1101C>G p.T367= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs1557808080, COSV100069451; called by muse, mutect2, varscan2
- SORCS3 | c.1953T>A p.V651= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100863523; called by muse, mutect2
- TARBP1 | c.2755C>T p.L919= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs1335318490, COSV99242099; called by muse, mutect2, varscan2
- TEK | c.93C>T p.S31= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV101193560; called by muse, mutect2, varscan2
- TLR5 | c.1428A>G p.E476= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100643386; called by muse, mutect2, varscan2
- TNS3 | c.186G>A p.T62= | Silent (SNP) | VAF 64/195 reads (33%) | catalogued as rs376868413; called by muse, mutect2, varscan2
- VAMP7 | c.543C>A p.A181= | Silent (SNP) | VAF 82/288 reads (28%) | catalogued as COSV99388039; called by muse, mutect2, varscan2
- ZNF582 | c.1554G>A p.*518= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100018954; called by muse, mutect2, varscan2
- ZNF681 | c.1092G>A p.K364= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs192553417; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109748T>C | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as rs760915604, COSV100456846; called by muse, mutect2, varscan2
